Somatic mutation profile of tumor specimen MP2PRT-PASVHK-TMP1-A (aliquot MP2PRT-PASVHK-TMP1-A-1-0-D-A80J-36) from MP2PRT case MP2PRT-PASVHK, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.5 years (1,641 days).
Specimen MP2PRT-PASVHK-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7f32d9c8-d486-4bb5-bcb7-10d39d8e45c2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASVHK-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASVHK-NB1-A-1-0-D-A80J-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/18cabc4b-c3da-4a91-ba2b-4572a0887caf

The open-access MAF lists 15 somatic variants for this specimen: 11 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Intron 2, Silent 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL14A1 | c.1357G>A p.D453N | Missense Mutation (SNP) | VAF 142/312 reads (46%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.767); catalogued as rs760449505, COSV52847994; called by muse, mutect2, varscan2
- FHL5 | c.553G>C p.E185Q | Missense Mutation (SNP) | VAF 166/397 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as COSV58739037; called by muse, mutect2, varscan2
- PCDHA3 | c.1535C>T p.A512V | Missense Mutation (SNP) | VAF 408/1007 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.819); catalogued as COSV100793723, COSV63542265; called by muse, mutect2, varscan2
- PCDHGB2 | c.392C>T p.P131L | Missense Mutation (SNP) | VAF 29/400 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763036184, COSV54006643; called by muse, mutect2
- TMEM31 | c.274G>C p.E92Q | Missense Mutation (SNP) | VAF 262/620 reads (42%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100129055; called by muse, mutect2, varscan2
- WFIKKN1 | c.902C>T p.P301L | Missense Mutation (SNP) | VAF 391/863 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.146); catalogued as rs777490530; called by muse, mutect2, varscan2
- ARHGAP17 | c.878C>G p.A293G | Missense Mutation (SNP) | VAF 192/439 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- C8orf34 | c.65C>G p.S22* | Nonsense Mutation (SNP) | VAF 328/779 reads (42%) | called by muse, mutect2, varscan2
- FSIP2 | c.10062A>T p.E3354D | Missense Mutation (SNP) | VAF 44/114 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MAP3K15 | c.1610C>A p.T537N | Missense Mutation (SNP) | VAF 75/205 reads (37%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- TEX9 | c.711G>A p.M237I | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MAST3 | c.2166C>T p.F722= | Silent (SNP) | VAF 221/534 reads (41%) | catalogued as rs573898349, COSV53218621; called by muse, mutect2, varscan2
- SERPINB6 | c.1041G>A p.T347= (on ENST00000612421 / NM_001271823.2; = p.T328= on NM_004568.6) | Silent (SNP) | VAF 237/570 reads (42%) | catalogued as rs756133384, COSV100177784; called by muse, mutect2, varscan2
- RABGAP1L | c.1711-89359C>A | Intron (SNP) | VAF 70/178 reads (39%) | called by muse, mutect2, varscan2
- UNC13B | c.761+4636G>A | Intron (SNP) | VAF 10/204 reads (5%) | called by muse, mutect2
